Somatic mutation profile of tumor specimen TCGA-AJ-A3I9-01A (aliquot TCGA-AJ-A3I9-01A-11D-A228-09) from TCGA case TCGA-AJ-A3I9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 52.4 years (19,139 days).
Specimen TCGA-AJ-A3I9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f28906ba-0fd9-4902-b8ab-7607605c42e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A3I9-10A (Blood Derived Normal), aliquot TCGA-AJ-A3I9-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0696873e-f3e8-4f4a-8461-434a730141a5

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 20, Silent 7, In Frame Del 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 81/90 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786204929, CM122894, COSV64288557, COSV64309376; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024del p.R342Efs*3 | Frame Shift Del (DEL) | VAF 12/18 reads (67%) | catalogued as rs1131691022, CM004908, COSV52665487; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AL021546.1 | c.80T>C p.V27A | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.762); catalogued as COSV99984881; called by muse, mutect2, varscan2
- ANKRD24 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1188795251, COSV99517594; called by muse, mutect2, varscan2
- CCDC172 | c.731T>C p.F244S | Missense Mutation (SNP) | VAF 50/52 reads (96%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs777480433, COSV100319818; called by muse, mutect2, varscan2
- EPB41L3 | c.2323A>G p.M775V | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1426142622, COSV100549369; called by muse, mutect2, varscan2
- FAM47C | c.148T>C p.F50L | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100792646; called by muse, mutect2
- FAT3 | c.537G>T p.Q179H | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV99966793; called by muse, mutect2, varscan2
- GK2 | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV62626715; called by muse, mutect2, varscan2
- LPIN1 | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs1461041127, COSV56765016; called by muse, mutect2, varscan2
- MAGI3 | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.098); catalogued as COSV100289329; called by muse, mutect2, varscan2
- PCDHGA10 | c.2339C>T p.A780V | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); catalogued as rs867995925, COSV53951158; called by muse, mutect2, varscan2
- PGS1 | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs377140180; called by muse, mutect2, varscan2
- RNF216 | c.228A>T p.E76D (on ENST00000425013 / NM_207116.3; = p.E133D on NM_207111.4) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.053); catalogued as rs768474255, COSV101111316; called by muse, mutect2, varscan2
- SLITRK3 | c.1343A>G p.Q448R | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV99579352; called by muse, mutect2, varscan2
- SPRYD4 | c.166T>G p.L56V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV100358369; called by muse, mutect2, varscan2
- UNC13A | c.3658C>T p.R1220C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs764119582, COSV53189928; called by muse, varscan2
- UQCRQ | c.74G>T p.R25L | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99737398; called by muse, mutect2
- WDFY3 | c.78G>A p.M26I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV99883790; called by muse, mutect2, varscan2
- WDR19 | c.2633G>A p.R878H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs369494725; called by muse, mutect2, varscan2
- WWC3 | c.1914-1G>A p.X638_splice | Splice Site (SNP) | VAF 17/42 reads (40%) | catalogued as COSV101081499; called by muse, mutect2, varscan2
- XKR9 | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101281937, COSV68773204; called by muse, mutect2
- PIK3R1 | c.1142_1144del p.I381del (on ENST00000521381 / NM_181523.3; = p.I111del on NM_181504.4) | In Frame Del (DEL) | VAF 24/47 reads (51%) | called by mutect2, pindel, varscan2
- CASKIN2 | c.177G>A p.G59= | Silent (SNP) | VAF 18/22 reads (82%) | catalogued as rs146822740; called by muse, mutect2, varscan2
- CPA2 | c.1200C>T p.A400= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs752355949, COSV99744049; called by mutect2, varscan2
- DDX39A | c.996C>T p.F332= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs772264761, COSV99660333; called by muse, mutect2, varscan2
- IKZF4 | c.516C>T p.N172= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs201788307, COSV100009161; called by muse, mutect2, varscan2
- KIAA1614 | c.3078C>T p.S1026= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV100799809; called by muse, mutect2, varscan2
- SOBP | c.168T>C p.G56= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs781699567, COSV100433197; called by muse, mutect2, varscan2
- ZMYM6 | c.2886T>C p.N962= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100593201; called by muse, mutect2, varscan2
